Gene-level copy-number profile of tumor specimen TCGA-5B-A90C-01A from TCGA case TCGA-5B-A90C, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 69.9 years (25,518 days).
Specimen TCGA-5B-A90C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.c6b007c6-f193-4f00-9792-c7968bcc261e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-5B-A90C-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/de585774-1b59-47da-8f6b-de248685276b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,304; copy number 2: 15,546; copy number 3: 19,854; copy number 4: 15,900; copy number 5: 4,256; copy number 6: 1,252; copy number 7: 363; copy number 8: 702; copy number 9: 113; copy number 10: 202; copy number 11: 39; copy number 12: 62; copy number 13: 123; copy number 14: 41; copy number 15: 21; copy number 17: 7; copy number 22: 8; copy number 26: 8; copy number 34: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-5B-A90C-01A-11D-A37M-01): tumor purity 0.83, ploidy 3.21, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,442,060–9,442,380, 1 gene: RN7SL5P.
- chr11:84,639,993–84,640,565, 1 gene: AP000852.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,610 genes in 38 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,026,738–8,122,702, 2 genes, copy number 8 (within-gene range 4–8): AL034417.2, AL034417.1.
- chr1:31,629,866–31,816,051, 8 genes, copy number 22 (within-gene range 3–22): PEF1, PEF1-AS1, AC114488.2, COL16A1, ADGRB2, MIR4254, AL354919.2, SPOCD1.
- chr1:115,641,970–115,768,714, 2 genes, copy number 7: VANGL1, CASQ2.
- chr3:8,980,591–9,363,053, 1 gene, copy number 7 (within-gene range 4–7): SRGAP3.
- chr3:9,192,493–9,398,579, 7 genes, copy number 7: SRGAP3-AS2, SRGAP3-AS3, SRGAP3-AS4, AC026191.1, PGAM1P4, THUMPD3-AS1, THUMPD3.
- chr5:50,396,192–53,881,051, 47 genes, copy number 7–12: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11, MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC027329.1, AC108114.1, FST, NDUFS4, LINC02105, ASS1P9, AC025175.1.
- chr5:53,897,464–53,951,599, 3 genes, copy number 7: AC025175.2, RNU6-272P, MIR581.
- chr7:38,977,909–40,099,580, 23 genes, copy number 7 (within-gene range 6–7): POU6F2, POU6F2-AS2, SNORA20B, POU6F2-AS1, AC011290.1, YAE1, AC011290.2, AC004837.3, AC004837.1, AC004837.4, RALA, AC004837.2, LINC00265, RNU6-719P, AC004987.3, CICP22, AC004987.2, AC004987.1, SSBL3P1, RWDD4P2, RN7SL496P, AC072061.1, CDK13.
- chr8:97,772,313–115,809,673, 253 genes, copy number 8–10 (broad region; genes not listed).
- chr8:116,022,686–116,022,779, 1 gene, copy number 8: RNA5SP276.
- chr9:30,388,935–37,592,604, 238 genes, copy number 8–11 (within-gene range 2–11) (broad region; genes not listed).
- chr9:37,636,688–37,832,117, 5 genes, copy number 11 (within-gene range 6–11): RAB1C, FRMPD1, RN7SKP171, TRMT10B, EXOSC3.
- chr10:17,214,239–18,043,292, 18 genes, copy number 7: VIM-AS1, VIM, AL133415.1, ST8SIA6, ST8SIA6-AS1, Y_RNA, PRPF38AP2, HACD1, AC069542.2, STAM-AS1, STAM, AC069542.1, TMEM236, MRC1, MIR511, AC069023.1, SLC39A12, SLC39A12-AS1.
- chr10:26,695,091–28,941,910, 57 genes, copy number 7: AL390961.3, PDSS1, HSPA8P3, AL390961.2, ABI1, AL139404.1, RNU6-946P, FAM238C, ANKRD26, RNU6-490P, YME1L1, MASTL, ACBD5, RNU2-24P, RNU7-12P, AL160291.1, LRRC37A6P, ARMC4P1, AL355493.6, RNU6-666P, AL355493.1, RNU6-452P, LINC02673, FAM210CP, TRIAP1P1, PTCHD3, RAB18, LINC02680, MKX, MKX-AS1, ARMC4, RN7SKP132, RPL36AP55, AL390866.1, MRPS21P5, MPP7, AL355501.1, MIR8086, MPP7-DT, ZNF101P1, U3, LINC02652, RPSAP10, RN7SKP39, WAC-AS1, WAC, RNU4ATAC6P, TPRKBP1, RNU6-1067P, BAMBI, LINC01517, AL355376.1, RNU6-270P, LINC00837, AL355376.2, RNA5SP308, RPL21P93.
- chr10:74,120,255–79,355,334, 81 genes, copy number 10–13 (broad region; genes not listed).
- chr10:79,382,328–79,409,274, 1 gene, copy number 10 (within-gene range 2–10): AL133481.1.
- chr10:90,622,143–92,427,620, 37 genes, copy number 8–15: AL390862.1, HTR7, RPP30, Y_RNA, ANKRD1, RNU6-740P, AL365434.1, AL365434.2, LINC00502, DDX18P6, NUDT9P1, AL731553.1, PCGF5, HECTD2, AL161798.1, RPS27P1, PPP1R3C, GAPDHP28, FAF2P1, TNKS2-AS1, TNKS2, SRP9P1, AL359198.2, FGFBP3, AL359198.1, BTAF1, CPEB3, AL365398.1, SDHCP2, EIF4A1P8, AL158040.1, NHP2P1, Y_RNA, MARCHF5, RNY3P12, MARK2P9, AL161652.1.
- chr10:115,093,365–115,948,999, 1 gene, copy number 12 (within-gene range 1–12): ATRNL1.
- chr10:115,819,842–116,911,788, 17 genes, copy number 12: NTAN1P1, GFRA1, AC012470.1, CCDC172, SNRPGP6, PNLIPRP3, HMGB3P8, RNU6-1090P, PNLIP, PNLIPP1, PNLIPRP1, PNLIPRP2, C10orf82, AC016825.1, HSPA12A, RPL5P27, ENO4.
- chr10:121,478,332–121,951,965, 7 genes, copy number 11 (within-gene range 4–11): FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1, Y_RNA, ATE1-AS1.
- chr11:55,262,155–56,527,503, 97 genes, copy number 8 (broad region; genes not listed).
- chr11:66,050,729–66,843,516, 52 genes, copy number 8 (within-gene range 5–8): SF3B2, AP006287.2, PACS1, AP000759.1, KLC2, AP001107.4, AP001107.8, AP001107.7, RAB1B, AP001107.1, AP001107.2, CNIH2, YIF1A, TMEM151A, AP001107.3, CD248, RIN1, AP001107.6, BRMS1, B4GAT1, AP001107.9, SLC29A2, Metazoa_SRP, BRD9P1, RNU1-84P, AP001107.5, NPAS4, AP002748.1, MRPL11, AP002748.3, PELI3, AP002748.4, DPP3, AP002748.5, BBS1, AP002748.6, ZDHHC24, ACTN3, AP002748.2, CTSF, CCDC87, CCS, RNU4-39P, RBM14, RBM14-RBM4, RBM4, RBM4B, SPTBN2, RN7SL12P, C11orf80, C1QBPP2, FTLP6.
- chr11:75,717,838–78,079,865, 66 genes, copy number 9–14 (within-gene range 2–14) (broad region; genes not listed).
- chr11:103,109,410–103,479,863, 1 gene, copy number 34 (within-gene range 2–34): DYNC2H1.
- chr11:103,402,013–103,409,657, 7 genes, copy number 34: MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1.
- chr12:32,679,200–32,745,650, 4 genes, copy number 9 (within-gene range 5–9): DNM1L, AC084824.2, Y_RNA, AC084824.5.
- chr14:18,333,726–21,456,126, 185 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr14:75,838,157–81,533,853, 102 genes, copy number 8–9 (broad region; genes not listed).
- chr17:27,874,645–31,859,291, 223 genes, copy number 7–13 (within-gene range 6–13) (broad region; genes not listed).
- chr17:33,688,803–34,156,000, 11 genes, copy number 10 (within-gene range 2–10): AC024614.2, AC024614.3, AC024614.4, AC024610.2, AC004147.4, AC024610.1, AC123769.1, TLK2P1, AC004147.1, AC004147.5, RNA5SP438.
- chr18:3,066,807–3,478,978, 15 genes, copy number 8: MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC.
- chr18:3,571,215–3,608,336, 4 genes, copy number 8: RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2.
- chr18:23,453,287–23,486,603, 1 gene, copy number 26 (within-gene range 4–26): RIOK3.
- chr18:23,485,000–23,672,748, 6 genes, copy number 26: AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27.
- chr18:23,709,825–23,710,287, 1 gene, copy number 26: RPL23AP77.
- chr19:13,099,033–13,842,928, 19 genes, copy number 9 (within-gene range 3–9): LYL1, TRMT1, NACC1, AC005546.1, AC011446.1, STX10, IER2, AC011446.3, AC011446.2, RPL12P42, CACNA1A, CCDC130, MRI1, AC008686.1, C19orf53, ZSWIM4, AC020916.2, RN7SL619P, AC020916.1.
- chr19:20,340,269–20,424,969, 1 gene, copy number 17 (within-gene range 3–17): ZNF826P.
- chr19:20,389,658–20,571,095, 6 genes, copy number 17: AC078899.2, MIR1270, BNIP3P22, AC008554.1, BNIP3P23, ZNF737.

Autosomal genes at a single copy (total copy number 1): 1,304. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
